CCDI case PBBRWM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/46a5a245-474f-42ec-82f3-f9fd3999a620

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 13.9 years (5,086 days).

Biospecimens (3 samples)
- Sample 0DFMIB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFSSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
